Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A181, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A181-06A (Metastatic).

12/19/10 *hm*

100-0-3

Melanoma NOS 8720/3
Site Code: Groin, C77.4

DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

years Female

HISTOPATHOLOGY REPORT

CLINICAL DETAILS

Metastatic melanoma R groin. Radical groin dissection R. Received fresh, portion of largest lymph node taken for tumour banking.

MACROSCOPIC DESCRIPTION

"RIGHT GROIN CONTENTS (FRESH) STAPLES UPPER". An oriented ellipse of skin and attached fibrofatty tissue 180 x 70 x 50mm, orientated with three staples marking upper. The overlying skin is tan coloured and unremarkable. The specimen is dissected from superior to inferior, there are up to nine lymph nodes identified, the largest measures 33mm in maximum diameter with tan white to brown cut surface.

A-C. One lymph node each

D. Four lymph nodes

E&F. Two sections from the largest lymph node

G. One lymph node

H. Sections from the skin.

Further blocks were taken after further fixation, no definite extra nodes were found

J-Q. Further blocks from the fibrofatty tissue.

MICROSCOPIC REPORT

"RIGHT GROIN CONTENTS (FRESH) STAPLES UPPER".

Metastatic melanoma virtually replaces 1 of 8 lymph nodes. The tumour is about 30mm across. There is no extranodal spread. Sections of the skin show no significant abnormality.

SUMMARY

RIGHT INGUINAL LYMPH NODE DISSECTION - METASTATIC MELANOMA IN 1 OF 8 NODES.

REPORTED BY: Dr

Printer

Source: NCI Genomic Data Commons file fc52c4ef-6325-46a8-98fc-d7047611a387 (TCGA-EE-A181.FF6D6361-9BE7-4367-ABBE-9A34753D7D51.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).